Surgical pathology report (de-identified scan), TCGA case TCGA-06-0744, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0744-01A (Primary Tumor).

[page 1 of 2]
TCGA-06-0744

Surgical Pathology Report

CLINICAL HISTORY
Not Given

OPERATIVE DIAGNOSES
Not Given

Operation/Specimen: A: Brain, left parietal, biopsy

PATHOLOGICAL DIAGNOSIS:
Brain, left parietal lobe, resection: Glioblastoma multiforme, proliferation
index (MIB-1): 20%

COMMENT
This is a glioblastoma with frequent mitosis, vascular hyperplasia and large
areas of necrosis.

PROCEDURES/ADDENDA
MGMT Promoter Methylation
Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

POSITIVE - Methylated MGMT promoter is detected.

Results-Comments
Received were paraffin curls labeled

lated [REDACTED]

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of
both methylated and unmethylated MGMT promoter sequences, with products
detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a
stand-alone diagnostic test. This test was developed and its performance
characteristics determined by the [REDACTED] laboratory as
required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for
specific uses by the U.S. Food and Drug Administration (FDA). The FDA has
determined that such clearance or approval is not necessary. These results are
provided for informational purposes only, and should be interpreted only in
the context of established procedures and/or diagnostic criteria.

[page 2 of 2]
GROSS DESCRIPTION

SPECIMEN: Left parietal.

FIXATIVE: Formalin.

GENERAL: A 2.5 x 2.0 x 1.0 cm., 2.18 gm. aggregate of multiple irregularly shaped pale red-tan to gray-tan tissue fragments. One of the larger fragments is sectioned.

SECTIONS: A1-A3 all submitted.

ICD-9(s):

191.1 191.1

Histo Data

Part A: Brain, left parietal, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
MIB1-DA x 1	1		
H/E x 1	2		
H/E x 1	3		

*** End of Report ***

Source: NCI Genomic Data Commons file 4737dcf1-220d-4c1f-a1f4-2620945fab6c (TCGA-06-0744.F01F0597-862D-4D9E-95DE-A00604F9A298.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).